TCGA case TCGA-EL-A3D0 — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: MD Anderson. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/63986dd0-63ba-4ee5-aa25-8ff2cbb762d3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 61 years; Vital status: Alive.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 61.9 years (22,622 days); Year of diagnosis: 2001; AJCC staging edition: 5th; AJCC pathologic T: T4; AJCC pathologic N: N1b; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Days to last follow up: 4,254 days (11.6 years); Tumor focality: Unifocal.
   Pathology details: Consistent pathology review: Yes; Extrathyroid extension: Moderate/Advanced (T4a); Lymph nodes positive: 9; Lymph nodes tested: 37; Measurement unit: Centimeters; Tumor depth measurement: 3; Tumor length measurement: 5; Tumor width measurement: 3.5.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 39 days; Days to treatment end: 39 days; Treatment dose: 150 mCi; Number of fractions: 1.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 953 days (2.6 years); Days to treatment end: 953 days (2.6 years); Treatment dose: 200 mCi; Number of fractions: 1.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 44 days; Disease response: With Tumor.
- Days to follow up: 4,254 days (11.6 years); Disease response: With Tumor.
- Imaging type: Ultrasound; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Evidence of progression type: Convincing Image Source; Timepoint: Initial Diagnosis.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EL-A3D0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 270 mg.
  Slide TCGA-EL-A3D0-01A-01-TSA: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 65; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-EL-A3D0-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EL-A3D0-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Classical/usual; Laterality: Left lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: Yes; Metastatic diagnosis confirmed by other: Papillary thyroid carcinoma; Metastasis site: Lung; New tumor event diagnosis indicator: No.
- Neoplasm dimension: Tumor size width: 5; Tumor size width: 3.
- Metastatic neoplasm confirmed diagnosis method names: Metastatic diagnosis confirmed by: Imaging Suspected.
- Follow-up form: Lost to follow-up: Yes; Tumor status: With tumor; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form, Radiation treatment: History radiation treatment to site of TCGA tumor: No.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: unknown treatment history.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 4,254 days; disease-specific survival: no event (censored), 4,254 days; progression-free interval: no event (censored), 4,254 days.
